Somatic mutation profile of tumor specimen C3N-05101-02 (aliquot CPT0438320010) from CPTAC case C3N-05101, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIID; Age at diagnosis: 76.9 years (28,084 days).
Specimen C3N-05101-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7667c98-2540-4ae1-a12d-05b421f5ff76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-05101-31 (Blood Derived Normal), aliquot CPT0444730005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf1db72e-5025-445e-9bd8-a422e7141e9d

The open-access MAF lists 557 somatic variants for this specimen: 376 protein-altering or splice-affecting, 158 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 342, Silent 158, Nonsense Mutation 22, Intron 19, Splice Region 4, Frame Shift Del 3, Splice Site 3, 5'Flank 3, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.5327C>T p.P1776L | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553187939, CM014303; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA2 | c.1901T>A p.V634D (on ENST00000614293; = p.V604D on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55798594; called by muse, mutect2, varscan2
- ABCC5 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 83/462 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs754448946, COSV55587447; called by muse, mutect2, varscan2
- ADGRV1 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67980007; called by muse, mutect2, varscan2
- ADGRV1 | c.13919G>A p.G4640E | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs727504706; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGL | c.2681C>T p.S894F | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs866082714, COSV54051116; called by muse, mutect2, varscan2
- AGPS | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs1418338955, COSV51562195; called by muse, mutect2, varscan2
- AKR1C4 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV54123589; called by muse, mutect2
- AMPD1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 63/283 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290122973; called by muse, mutect2, varscan2
- APLP1 | c.1678C>T p.P560S (on ENST00000221891 / NM_001024807.3; = p.P559S on NM_005166.4) | Missense Mutation (SNP) | VAF 84/335 reads (25%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.525); catalogued as rs775928516, COSV55704124; called by muse, mutect2, varscan2
- APOBEC2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 103/591 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.321); catalogued as rs1065197, COSV99775374; called by muse, mutect2, varscan2
- ARHGEF1 | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 150/618 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs1555849676; called by muse, mutect2
- ASXL3 | c.4538C>G p.P1513R | Missense Mutation (SNP) | VAF 93/434 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); catalogued as rs749918007, COSV99326462; called by muse, mutect2, varscan2
- BAIAP3 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 71/390 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs763235929, COSV60978358; called by muse, mutect2, varscan2
- BATF | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 134/605 reads (22%) | catalogued as COSV54375188; called by muse, mutect2, varscan2
- BRAF | c.2323C>T p.R775W (on ENST00000288602 / NM_001374244.1; = p.R735W on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 219/514 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99958201; called by muse, mutect2, varscan2
- BRINP2 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 111/728 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs201898561, COSV64176183; called by muse, mutect2, varscan2
- C2CD5 | c.2107G>A p.G703S | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as rs764449055; called by muse, mutect2, varscan2
- CACNA1A | c.1185G>A p.W395* | Nonsense Mutation (SNP) | VAF 56/354 reads (16%) | catalogued as COSV64212685; called by muse, mutect2
- CACNA1B | c.4793C>T p.A1598V | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99499661; called by muse, mutect2, varscan2
- CACNA1H | c.5659G>A p.G1887S | Missense Mutation (SNP) | VAF 156/666 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as rs1165459914; called by muse, mutect2, varscan2
- CACNA1H | c.6764C>T p.S2255F | Missense Mutation (SNP) | VAF 143/614 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.276); catalogued as rs746214213, COSV52358267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADM2 | c.883C>T p.R295* (on ENST00000407528 / NM_001167674.2; = p.R297* on NM_153184.4) | Nonsense Mutation (SNP) | VAF 71/364 reads (20%) | catalogued as rs781077819, COSV67361182; called by muse, mutect2, varscan2
- CBLN3 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV52162039; called by muse, mutect2, varscan2
- CCDC151 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 58/333 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV52951560; called by muse, mutect2, varscan2
- CDH5 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 79/378 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as COSV58518369; called by muse, mutect2, varscan2
- CECR2 | c.4275G>A p.M1425I (on ENST00000342247 / NM_001290047.2; = p.M1241I on NM_001290046.1) | Missense Mutation (SNP) | VAF 102/558 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs572451277; called by muse, mutect2, varscan2
- CEP85 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 94/490 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs368381610; called by muse, mutect2, varscan2
- CFAP46 | c.7139G>A p.G2380E | Missense Mutation (SNP) | VAF 99/467 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.196); catalogued as COSV54149814; called by muse, mutect2, varscan2
- CFAP92 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 67/333 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.225); catalogued as rs754077147; called by muse, mutect2, varscan2
- CFH | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 145/358 reads (41%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.535); catalogued as COSV66408729; called by muse, mutect2, varscan2
- CLCN5 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 66/432 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as CD067154; called by muse, mutect2, varscan2
- CLVS1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 69/391 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs143211270, COSV57975512, COSV99073593; called by muse, mutect2, varscan2
- CNGA4 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 103/454 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66006603; called by muse, mutect2, varscan2
- CNGB3 | c.2201G>A p.G734E | Missense Mutation (SNP) | VAF 62/432 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs757799031, COSV60686027, COSV60687783; called by muse, mutect2, varscan2
- COL4A2 | c.4316C>T p.P1439L | Missense Mutation (SNP) | VAF 76/443 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.102); catalogued as rs538325329; called by muse, mutect2, varscan2
- COL4A5 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 91/455 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60356999; called by muse, mutect2, varscan2
- COL4A5 | c.3358C>T p.L1120F | Missense Mutation (SNP) | VAF 58/329 reads (18%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.999); catalogued as COSV60360821; called by muse, mutect2, varscan2
- CSMD1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201992115, COSV68170651; called by muse, mutect2, varscan2
- CYP2C18 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs770145786, COSV53669438; called by muse, mutect2, varscan2
- CYP2R1 | c.117C>G p.F39L | Missense Mutation (SNP) | VAF 77/462 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58126687; called by muse, mutect2, varscan2
- CYP4F12 | c.832C>A p.L278I | Missense Mutation (SNP) | VAF 21/486 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV61173455; called by muse, mutect2
- DAPK1 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 59/328 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.981); catalogued as rs780995964; called by muse, mutect2, varscan2
- DPRX | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 104/530 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs769091377, COSV64949952; called by muse, mutect2, varscan2
- DSCAM | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as rs267606128, COSV68029375; called by muse, mutect2, varscan2
- E2F4 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 93/443 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV58876750; called by muse, mutect2, varscan2
- EDEM1 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as rs775845865; called by muse, mutect2, varscan2
- EML5 | c.5311G>A p.G1771R (on ENST00000380664; = p.G1779R on NM_183387.3) | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.98); catalogued as rs1364983506; called by muse, mutect2, varscan2
- ENAM | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 94/428 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV68536863; called by muse, mutect2, varscan2
- EPHB6 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 162/1095 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759611724; called by muse, mutect2, varscan2
- EPS15L1 | c.2168C>T p.P723L | Missense Mutation (SNP) | VAF 57/352 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs865983780, COSV50170185; called by muse, mutect2, varscan2
- ERBB4 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV53557978; called by muse, mutect2
- ERC2 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs571267313, COSV55619482; called by muse, mutect2, varscan2
- EXPH5 | c.3613C>T p.L1205F | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as rs1192860515, COSV56209344; called by muse, mutect2, varscan2
- F10 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 123/384 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM025195, COSV65022032, COSV65022246; called by muse, mutect2, varscan2
- FHOD1 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1305208794; called by muse, mutect2, varscan2
- FLNB | c.6160G>A p.D2054N | Missense Mutation (SNP) | VAF 93/451 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs765559414; called by muse, mutect2, varscan2
- FREM1 | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 74/321 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1438943666, COSV66529989; called by muse, mutect2, varscan2
- FSIP2 | c.6200A>G p.D2067G | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1406608198; called by muse, mutect2, varscan2
- FUT9 | c.588G>A p.W196* | Nonsense Mutation (SNP) | VAF 147/367 reads (40%) | catalogued as COSV56156530; called by muse, mutect2, varscan2
- GCNT1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 84/442 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs656106, COSV65057049; called by muse, mutect2, varscan2
- GFPT1 | c.772C>T p.R258C (on ENST00000357308 / NM_001244710.2; = p.R240C on NM_002056.4) | Missense Mutation (SNP) | VAF 54/360 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV61947026; called by muse, mutect2, varscan2
- GFRAL | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 143/524 reads (27%) | catalogued as COSV61228659; called by muse, mutect2, varscan2
- GOLGA6L22 | c.1430G>A p.R477K | Missense Mutation (SNP) | VAF 323/850 reads (38%) | SIFT tolerated (0.17); catalogued as rs578025800; called by muse, mutect2, varscan2
- GPR158 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 103/481 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as rs1028057427, COSV66270440; called by muse, mutect2, varscan2
- GPR85 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 277/616 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs868610587, COSV51783347; called by muse, mutect2, varscan2
- GRM8 | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 207/544 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58854770; called by muse, mutect2, varscan2
- GRXCR2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 66/435 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs447402, COSV65060697; called by muse, mutect2, varscan2
- GUCY2D | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 142/735 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1304984076; called by muse, mutect2, varscan2
- HCRTR2 | c.1106-1G>A p.X369_splice | Splice Site (SNP) | VAF 55/320 reads (17%) | catalogued as COSV100904245; called by muse, mutect2, varscan2
- HECTD4 | c.8347C>T p.R2783* | Nonsense Mutation (SNP) | VAF 84/402 reads (21%) | catalogued as rs776708090; called by muse, mutect2, varscan2
- HPCA | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 72/353 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs868629310, COSV65103142; called by muse, mutect2, varscan2
- HRNR | c.2357G>A p.G786E | Missense Mutation (SNP) | VAF 102/731 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.703); catalogued as rs761620569; called by muse, mutect2, varscan2
- IFNA14 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 59/253 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.078); catalogued as rs764012910; called by muse, mutect2, varscan2
- IGHG3 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 114/664 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1458265564; called by muse, mutect2, varscan2
- IL1R1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52104862; called by muse, mutect2, varscan2
- INHBA | c.1121A>G p.N374S | Missense Mutation (SNP) | VAF 316/728 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.213); catalogued as COSV54225444; called by muse, mutect2, varscan2
- ITGA4 | c.2785G>A p.D929N | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as COSV59215187; called by muse, mutect2, varscan2
- ITGA7 | c.940G>A p.G314R (on ENST00000555728; = p.G270R on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs776086093; called by muse, mutect2, varscan2
- ITGB1BP2 | c.117T>C p.G39= | Splice Region (SNP) | VAF 90/437 reads (21%) | catalogued as COSV52135768; called by muse, mutect2, varscan2
- ITGB2 | c.2254C>T p.H752Y (on ENST00000302347; = p.H728Y on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/456 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56612548; called by muse, mutect2, varscan2
- JCAD | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 67/343 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs756849043, COSV64759331; called by muse, mutect2, varscan2
- KCNQ2 | c.2089G>A p.G697S (on ENST00000359125 / NM_172107.4; = p.G669S on NM_004518.6) | Missense Mutation (SNP) | VAF 244/681 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); catalogued as rs1319597206; called by muse, mutect2, varscan2
- KIAA1755 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 92/526 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as rs868839894, COSV54080724; called by muse, mutect2, varscan2
- KIF26B | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 372/887 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs1034978766, COSV68572526; called by muse, mutect2, varscan2
- KRT86 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 61/394 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as rs1239206562; called by muse, mutect2, varscan2
- LACTB2 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 111/294 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs753623930, COSV52567341; called by muse, mutect2, varscan2
- LARGE1 | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 80/451 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV61671742; called by muse, mutect2, varscan2
- LMOD3 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 87/508 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as rs1318711844; called by muse, mutect2, varscan2
- LY96 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.381); catalogued as COSV53026111; called by muse, mutect2, varscan2
- MAN1C1 | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 72/339 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs546055362; called by muse, mutect2, varscan2
- MAP3K21 | c.2956C>T p.L986F | Missense Mutation (SNP) | VAF 116/719 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV64042595; called by muse, mutect2, varscan2
- MARVELD3 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 89/486 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51705904; called by muse, mutect2, varscan2
- MFAP5 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 67/350 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV100848146; called by muse, mutect2, varscan2
- MINDY4B | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 80/448 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.106); catalogued as rs1434122474; called by muse, mutect2, varscan2
- MROH2B | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.344); catalogued as rs1225723939; called by muse, mutect2, varscan2
- MUC12 | c.13424G>A p.W4475* (on ENST00000379442; = p.W4332* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 232/4259 reads (5%) | catalogued as rs1380294623; called by muse, mutect2
- MUC4 | c.5732C>T p.S1911F | Missense Mutation (SNP) | VAF 144/1590 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV62171559; called by muse, mutect2
- MUC5AC | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 76/431 reads (18%) | SIFT deleterious (0); catalogued as rs1478733681; called by muse, mutect2, varscan2
- MXRA5 | c.6016G>A p.E2006K | Missense Mutation (SNP) | VAF 130/600 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV54230410; called by muse, mutect2, varscan2
- NCKAP1L | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 76/354 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as COSV53206940; called by muse, mutect2, varscan2
- NEB | c.3656C>T p.A1219V | Missense Mutation (SNP) | VAF 80/379 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs760487639; called by muse, mutect2, varscan2
- NOS1 | c.2422C>T p.L808F | Missense Mutation (SNP) | VAF 85/389 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100500513, COSV100501344; called by muse, mutect2, varscan2
- NPHS1 | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 70/312 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as rs115976159, COSV62287071; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPTXR | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 211/615 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606249, COSV60727837, COSV60729766; called by muse, mutect2, varscan2
- NR3C2 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60993950; called by muse, mutect2, varscan2
- NRG3 | c.1158G>A p.K386= | Splice Region (SNP) | VAF 65/252 reads (26%) | catalogued as rs267602593, COSV64548620; called by muse, mutect2, varscan2
- NTNG1 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs1009840067, COSV100903705; called by muse, varscan2
- OR2F2 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 90/723 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV68832948; called by muse, mutect2, varscan2
- OR3A2 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV101375096; called by muse, mutect2, varscan2
- OR4K13 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 63/347 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs1038673563; called by muse, mutect2, varscan2
- OR4K17 | c.-32-1G>A | Splice Site (SNP) | VAF 49/278 reads (18%) | catalogued as COSV100210817; called by muse, mutect2, varscan2
- OR51I1 | c.680T>C p.M227T | Missense Mutation (SNP) | VAF 91/484 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs775289416; called by muse, mutect2, varscan2
- OR52E8 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 65/354 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs781170349, COSV66205287; called by muse, mutect2, varscan2
- OR52L1 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 93/490 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as rs759878165; called by muse, varscan2
- OR56A5 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 99/420 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.248); catalogued as rs1032428934; called by muse, mutect2, varscan2
- OR6C4 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV67793053; called by muse, mutect2, varscan2
- OR6T1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 102/392 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868745413, COSV58306274, COSV58307592; called by muse, mutect2, varscan2
- OR8K1 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 70/431 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV54402220, COSV54402616; called by muse, mutect2, varscan2
- OR8K3 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 111/533 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as COSV57131594; called by muse, mutect2, varscan2
- OR8S1 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 26/348 reads (7%) | PolyPhen possibly damaging (0.791); catalogued as rs987596474; called by muse, mutect2
- OTOG | c.2854G>A p.G952R | Missense Mutation (SNP) | VAF 61/309 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61134220; called by muse, mutect2, varscan2
- PABPC5 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 103/536 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV100442272; called by muse, mutect2, varscan2
- PAX7 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 140/518 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64753495; called by muse, mutect2, varscan2
- PEX5 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 68/390 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV56955802; called by muse, varscan2
- PHKA1 | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 148/552 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.097); catalogued as COSV100263730, COSV59812104; called by muse, mutect2, varscan2
- PIP4K2C | c.490A>T p.S164C | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV100723881; called by muse, mutect2, varscan2
- PKNOX1 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 71/468 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1183029604; called by muse, mutect2, varscan2
- PLAUR | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 101/464 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.805); catalogued as rs771886940; called by muse, mutect2, varscan2
- PLEKHF2 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 138/344 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as rs1458223910; called by muse, mutect2, varscan2
- PLEKHS1 | c.1144C>T p.L382F | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99054439; called by muse, mutect2, varscan2
- POLE | c.6232C>T p.R2078W | Missense Mutation (SNP) | VAF 107/534 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs1060500867; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRDM9 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 160/769 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV99691292; called by muse, mutect2, varscan2
- PRRC2B | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 18/644 reads (3%) | catalogued as COSV61940213; called by muse, mutect2
- PRSS35 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 118/299 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs776819854, COSV63800274; called by muse, mutect2, varscan2
- PTPRT | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 112/323 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.697); catalogued as rs724159838, COSV61960464; called by muse, mutect2, varscan2
- PYHIN1 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 288/664 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV63723832; called by muse, mutect2, varscan2
- RBMXL3 | c.1877G>A p.G626E | Missense Mutation (SNP) | VAF 170/782 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as rs782675307; called by muse, mutect2, varscan2
- RETNLB | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs999385271; called by muse, mutect2, varscan2
- RGS7BP | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 36/192 reads (19%) | catalogued as COSV61835503; called by muse, mutect2, varscan2
- ROR1 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 94/441 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs866948780; called by muse, mutect2, varscan2
- RPE65 | c.1022T>G p.L341* | Nonsense Mutation (SNP) | VAF 45/209 reads (22%) | catalogued as CM983763, COSV52017692; called by muse, mutect2, varscan2
- RRP15 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 200/491 reads (41%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV65117929; called by muse, mutect2, varscan2
- S100PBP | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 83/408 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs577024048, COSV100758312; called by muse, mutect2, varscan2
- SAG | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 119/558 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101300716; called by muse, mutect2, varscan2
- SAMD9L | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 53/515 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs759789726; called by muse, mutect2, varscan2
- SEZ6L2 | c.1028C>T p.P343L (on ENST00000308713 / NM_001114099.3; = p.P273L on NM_012410.4) | Missense Mutation (SNP) | VAF 76/347 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423705655; called by muse, mutect2, varscan2
- SH3KBP1 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 96/439 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268380349, COSV101115053; called by muse, mutect2, varscan2
- SHANK1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 92/446 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV53253928; called by muse, mutect2, varscan2
- SHISA9 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 99/474 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as rs774111296, COSV69637351; called by muse, mutect2, varscan2
- SLCO1C1 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1299053563; called by muse, mutect2, varscan2
- SNAPC4 | c.3640C>T p.P1214S | Missense Mutation (SNP) | VAF 123/627 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.196); catalogued as COSV53737869; called by muse, mutect2, varscan2
- SNCAIP | c.1706C>T p.S569F | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV54416399; called by muse, mutect2, varscan2
- SNRNP70 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 125/644 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs1461394589; called by muse, mutect2, varscan2
- SNTG2 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 88/391 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100423384; called by muse, mutect2, varscan2
- SORCS3 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 128/593 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs780644787; called by muse, mutect2, varscan2
- SORCS3 | c.3124G>A p.D1042N | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV100864830; called by muse, mutect2, varscan2
- SSC5D | c.2923A>G p.T975A | Missense Mutation (SNP) | VAF 78/402 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs748906645; called by muse, mutect2, varscan2
- SUCO | c.3567T>G p.N1189K | Missense Mutation (SNP) | VAF 64/570 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs910068164; called by muse, mutect2, varscan2
- SYNPO2 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 124/556 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1356729558; called by muse, varscan2
- SYT10 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 72/324 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs866874853, COSV104391111, COSV57337722; called by muse, mutect2, varscan2
- TAS1R1 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 125/586 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as rs1290140699; called by muse, mutect2, varscan2
- TCHHL1 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 61/469 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs867934698; called by muse, mutect2, varscan2
- TENM4 | c.6698G>A p.R2233Q | Missense Mutation (SNP) | VAF 110/492 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs561808396; called by muse, mutect2, varscan2
- TEX47 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 152/393 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.075); catalogued as rs867402496, COSV51878249; called by muse, mutect2, varscan2
- THSD7B | c.4679T>C p.V1560A (on ENST00000272643; = p.V1558A on NM_001316349.2) | Missense Mutation (SNP) | VAF 61/298 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55687934; called by muse, mutect2, varscan2
- TKTL2 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 69/378 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as rs1560904567, COSV54918270; called by muse, mutect2, varscan2
- TMEM217 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 66/426 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs866950807; called by muse, varscan2
- TPRG1 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 89/439 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.975); catalogued as COSV61465244; called by muse, mutect2, varscan2
- TRHR | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.192); catalogued as rs1372752330, COSV100304649; called by muse, mutect2, varscan2
- TRIM48 | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 104/501 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV70163566; called by muse, mutect2, varscan2
- TRPC4 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 102/399 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59013427; called by muse, mutect2, varscan2
- TSEN2 | c.1203del p.W401* | Frame Shift Del (DEL) | VAF 82/486 reads (17%) | catalogued as COSV99539002; called by mutect2, pindel, varscan2
- TTLL11 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 73/293 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); catalogued as COSV58654476; called by muse, mutect2, varscan2
- TTN | c.48383T>G p.L16128R (on ENST00000591111; = p.L8704R on NM_003319.4) | Missense Mutation (SNP) | VAF 51/255 reads (20%) | PolyPhen possibly damaging (0.468); catalogued as COSV60156585; called by muse, mutect2, varscan2
- TTN | c.42823G>A p.E14275K (on ENST00000591111; = p.E6851K on NM_003319.4) | Missense Mutation (SNP) | VAF 38/236 reads (16%) | PolyPhen benign (0); catalogued as COSV60050409; called by muse, mutect2, varscan2
- TUFM | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 75/363 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051527670; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2168C>T p.P723L | Missense Mutation (SNP) | VAF 98/570 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs771598912, COSV51962263; called by muse, mutect2, varscan2
- UMODL1 | c.3728C>A p.T1243N (on ENST00000408910 / NM_001004416.2; = p.T1371N on NM_173568.3) | Missense Mutation (SNP) | VAF 58/421 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs1465869094; called by muse, mutect2, varscan2
- USP19 | c.3022G>A p.D1008N | Missense Mutation (SNP) | VAF 77/342 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV60045706; called by muse, mutect2, varscan2
- WDR49 | c.784C>T p.R262* (on ENST00000308378 / NM_001366158.1; = p.R603* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 33/186 reads (18%) | catalogued as rs200139077; called by muse, mutect2, varscan2
- WDR49 | c.637G>A p.D213N (on ENST00000308378 / NM_001366158.1; = p.D554N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/313 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1413574313; called by muse, mutect2, varscan2
- ZFX | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 141/593 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1280498890, COSV100457481; called by muse, mutect2, varscan2
- ZNF222 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 64/343 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51827698; called by muse, mutect2, varscan2
- ZNF560 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.15); catalogued as COSV100038811, COSV56868746; called by muse, mutect2, varscan2
- ZNF711 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 122/588 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52153945; called by muse, mutect2, varscan2
- ZXDA | c.1924G>A p.G642R | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1276660590; called by muse, mutect2, varscan2
- ABCA12 | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA2 | c.1900G>A p.V634I (on ENST00000614293; = p.V604I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ADAD2 | c.338C>G p.A113G | Missense Mutation (SNP) | VAF 144/655 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADAMTS10 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 80/380 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ADAMTS20 | c.2315T>A p.F772Y | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY8 | c.2390T>A p.F797Y | Missense Mutation (SNP) | VAF 66/460 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ADGRE3 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 74/385 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADGRV1 | c.1889G>A p.S630N | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRV1 | c.10696A>T p.I3566L | Missense Mutation (SNP) | VAF 62/314 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.014); called by muse, mutect2
- ADGRV1 | c.10698A>G p.I3566M | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- ADGRV1 | c.18472C>T p.Q6158* | Nonsense Mutation (SNP) | VAF 67/302 reads (22%) | called by muse, mutect2, varscan2
- AGBL5 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 75/328 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- AGTR2 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 95/536 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALB | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ANKRD62 | c.1751A>G p.E584G | Missense Mutation (SNP) | VAF 63/284 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ANKRD66 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 122/401 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO1 | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 105/466 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ANXA1 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ARHGAP23 | c.4266G>T p.W1422C | Missense Mutation (SNP) | VAF 113/541 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ARHGAP39 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 261/567 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGEF1 | c.2097T>A p.D699E | Missense Mutation (SNP) | VAF 152/628 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- ARHGEF10L | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 96/477 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARL3 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 48/295 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ATP2A3 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 115/507 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ATP8B1 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- ATRX | c.5315C>T p.S1772F | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTAF1 | c.5017A>C p.T1673P | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTBD8 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- C6orf62 | c.494A>G p.D165G | Missense Mutation (SNP) | VAF 66/452 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CACNA1E | c.5374C>A p.L1792M | Missense Mutation (SNP) | VAF 57/340 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CAMK4 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CAPN15 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 153/634 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- CAPZA3 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 59/363 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CBLC | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 79/427 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBWD6 | c.857A>G p.K286R | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.043); called by muse, mutect2
- CCDC102A | c.1363A>T p.K455* | Nonsense Mutation (SNP) | VAF 116/571 reads (20%) | called by muse, mutect2, varscan2
- CD22 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 84/467 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- CDSN | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 275/919 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CEACAM6 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 83/434 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CEP72 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 81/346 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CFAP20DC | c.1922C>T p.S641F | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CHST12 | c.408_423del p.S136Rfs*14 | Frame Shift Del (DEL) | VAF 333/888 reads (38%) | called by mutect2, pindel, varscan2
- CLTRN | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 63/284 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNBD1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 166/404 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- COL12A1 | c.4859C>T p.S1620F | Missense Mutation (SNP) | VAF 105/345 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CPXM2 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 91/457 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- DBX2 | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 53/305 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DCHS2 | c.1946T>G p.V649G | Missense Mutation (SNP) | VAF 93/485 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- DNAH5 | c.5690G>A p.R1897K | Missense Mutation (SNP) | VAF 40/259 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- DNAI2 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 95/508 reads (19%) | called by muse, mutect2, varscan2
- DOP1B | c.4577C>T p.S1526F | Missense Mutation (SNP) | VAF 107/504 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DPPA4 | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- EDARADD | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 62/547 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.04); called by muse, mutect2
- EFCAB7 | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ENTPD6 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EP400 | c.8651C>T p.S2884F | Missense Mutation (SNP) | VAF 103/524 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- EPHA6 | c.3115G>A p.E1039K | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EPM2AIP1 | c.926A>G p.K309R | Missense Mutation (SNP) | VAF 102/445 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM186A | c.3841C>T p.P1281S | Missense Mutation (SNP) | VAF 121/586 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM83F | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 191/571 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FGD6 | c.3869G>A p.R1290K | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG | c.7454C>T p.S2485F | Missense Mutation (SNP) | VAF 351/770 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- FRMPD4 | c.3152G>A p.G1051E | Missense Mutation (SNP) | VAF 145/616 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- FSIP2 | c.7441G>A p.G2481S | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FUT5 | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 139/658 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- FZD4 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 69/404 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GABRG3 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 139/319 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GIMAP2 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 90/610 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- GLMP | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 316/779 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.232); called by muse, mutect2
- GMPS | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GPATCH2L | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 77/410 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- GPRC6A | c.2618C>T p.S873F | Missense Mutation (SNP) | VAF 154/406 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- HAUS6 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HCFC1R1 | c.221A>T p.H74L | Missense Mutation (SNP) | VAF 132/594 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- HCN2 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- HEATR4 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 126/487 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- HERC1 | c.13303A>G p.T4435A | Missense Mutation (SNP) | VAF 282/658 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HNRNPL | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 73/363 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- HOXD3 | c.290A>C p.N97T | Missense Mutation (SNP) | VAF 114/516 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by mutect2, varscan2
- HPRT1 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 80/346 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSD17B6 | c.640A>C p.T214P | Missense Mutation (SNP) | VAF 72/429 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- IFNA17 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 91/361 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV6-1 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 69/332 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- IGLC7 | c.125G>A p.W42* | Nonsense Mutation (SNP) | VAF 142/770 reads (18%) | called by muse, mutect2
- IQCN | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 136/644 reads (21%) | called by muse, mutect2, varscan2
- IRAK3 | c.1465T>A p.L489I | Missense Mutation (SNP) | VAF 85/401 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- JCAD | c.1151G>A p.G384D | Missense Mutation (SNP) | VAF 122/629 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- JMJD6 | c.882C>A p.F294L | Missense Mutation (SNP) | VAF 101/477 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- KCNB2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 85/591 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- KCNB2 | c.1307G>A p.R436K | Missense Mutation (SNP) | VAF 251/588 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- KCNC3 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAMA1 | c.8309G>A p.G2770E | Missense Mutation (SNP) | VAF 121/478 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- LCOR | c.847C>A p.Q283K | Missense Mutation (SNP) | VAF 110/453 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- LINC00514 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- LUM | c.647A>G p.K216R | Missense Mutation (SNP) | VAF 77/452 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- MAGEC1 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 94/602 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); called by muse, varscan2
- MAGEC3 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 125/525 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MAP3K11 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 112/533 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP4K3 | c.2030T>C p.V677A | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- MEI1 | c.1498T>C p.F500L | Missense Mutation (SNP) | VAF 55/419 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MPEG1 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 84/381 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- MROH2B | c.2378A>G p.E793G | Missense Mutation (SNP) | VAF 68/368 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYF5 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 68/364 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO15A | c.9750dup p.F3251Lfs*3 | Frame Shift Ins (INS) | VAF 61/367 reads (17%) | called by mutect2, pindel, varscan2
- MYOM3 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 114/537 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- MYRFL | c.1764C>T p.I588= | Splice Region (SNP) | VAF 53/286 reads (19%) | called by muse, varscan2
- NAA80 | c.559G>C p.G187R (on ENST00000417393 / NM_001200018.2; = p.G209R on NM_012191.4) | Missense Mutation (SNP) | VAF 141/688 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOA1 | c.3362A>G p.H1121R | Missense Mutation (SNP) | VAF 62/383 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- NCOA2 | c.3905C>T p.P1302L | Missense Mutation (SNP) | VAF 150/349 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NEU4 | c.952G>C p.E318Q (on ENST00000391969 / NM_001167602.3; = p.E330Q on NM_080741.4) | Missense Mutation (SNP) | VAF 225/841 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NFAT5 | c.3139C>T p.Q1047* | Nonsense Mutation (SNP) | VAF 73/316 reads (23%) | called by muse, mutect2, varscan2
- NFATC1 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 152/739 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- NPIPB11 | c.1774C>T p.H592Y | Missense Mutation (SNP) | VAF 125/780 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NTNG1 | c.1309T>C p.F437L | Missense Mutation (SNP) | VAF 52/298 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, varscan2
- OR2V1 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 108/475 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- OR7D2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 69/371 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- P2RY4 | c.1081A>G p.R361G | Missense Mutation (SNP) | VAF 81/445 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAFAH1B1 | c.1150dup p.T384Nfs*45 | Frame Shift Ins (INS) | VAF 45/305 reads (15%) | called by mutect2, pindel, varscan2
- PCDH10 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 91/490 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- PCDH11X | c.2851C>T p.Q951* | Nonsense Mutation (SNP) | VAF 153/668 reads (23%) | called by muse, mutect2, varscan2
- PCDHB14 | c.1747G>A p.G583S | Missense Mutation (SNP) | VAF 68/600 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PGLYRP3 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 354/749 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PITX1 | c.728A>G p.N243S | Missense Mutation (SNP) | VAF 114/572 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PKHD1L1 | c.2436G>T p.R812S | Missense Mutation (SNP) | VAF 53/432 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKHD1L1 | c.8921C>T p.S2974L | Missense Mutation (SNP) | VAF 105/268 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PLEC | c.2496C>T p.S832= (on ENST00000322810 / NM_201380.4; = p.S722= on NM_000445.5) | Splice Region (SNP) | VAF 214/448 reads (48%) | called by muse, mutect2, varscan2
- POLQ | c.5330C>T p.P1777L | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPEF2 | c.2124A>C p.K708N | Missense Mutation (SNP) | VAF 104/503 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PPP1R2C | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PREX2 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 111/325 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- PRUNE2 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 99/456 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- PSAPL1 | c.995T>G p.I332S | Missense Mutation (SNP) | VAF 101/545 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PTGER4 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 94/420 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPN21 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- PYGO2 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 270/624 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PYROXD2 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RAB27B | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RAD51AP2 | c.3120G>A p.M1040I | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAI2 | c.755T>A p.M252K | Missense Mutation (SNP) | VAF 151/704 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RBM25 | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 111/540 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- RBM45 | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- RCOR1 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- RELN | c.4819C>T p.Q1607* | Nonsense Mutation (SNP) | VAF 194/486 reads (40%) | called by muse, mutect2, varscan2
- RHOJ | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 87/398 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHOXF2B | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 124/694 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RNF123 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 88/447 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- RPS24 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 102/500 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SBSPON | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 233/547 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SCN11A | c.3742C>T p.L1248F | Missense Mutation (SNP) | VAF 49/294 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SELENOI | c.722A>G p.N241S | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SETD5 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 81/402 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SLC35A2 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 154/740 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SLC35A2 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 154/746 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SLC35A4 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 125/515 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- SLC7A2 | c.1463A>T p.Q488L (on ENST00000494857 / NM_001370338.1; = p.Q527L on NM_003046.6) | Missense Mutation (SNP) | VAF 74/377 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- STAG1 | c.3218C>T p.S1073L | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- STARD8 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 119/537 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- SYCP2 | c.2134A>T p.K712* | Nonsense Mutation (SNP) | VAF 86/323 reads (27%) | called by muse, mutect2, varscan2
- SYNPR | c.268T>G p.F90V | Missense Mutation (SNP) | VAF 96/411 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TENM1 | c.226T>C p.F76L | Missense Mutation (SNP) | VAF 140/396 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TENM3 | c.5201G>A p.R1734K | Missense Mutation (SNP) | VAF 85/424 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- TLR5 | c.2046T>A p.H682Q | Missense Mutation (SNP) | VAF 74/663 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM218 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 78/319 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TMEM51 | c.444G>C p.E148D | Missense Mutation (SNP) | VAF 100/494 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNK2 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 151/686 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNS4 | c.953A>G p.H318R | Missense Mutation (SNP) | VAF 130/556 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- TP53BP1 | c.773+1G>A p.X258_splice | Splice Site (SNP) | VAF 113/250 reads (45%) | called by muse, mutect2, varscan2
- TRABD2A | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 96/479 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAJ18 | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 76/361 reads (21%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRANK1 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV6 | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 104/447 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TRIM49B | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TSPEAR | c.857G>A p.W286* | Nonsense Mutation (SNP) | VAF 76/373 reads (20%) | called by muse, mutect2, varscan2
- TTF1 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TTN | c.99130G>A p.E33044K (on ENST00000591111; = p.E25620K on NM_003319.4) | Missense Mutation (SNP) | VAF 93/433 reads (21%) | PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TTN | c.71584G>A p.E23862K (on ENST00000591111; = p.E16438K on NM_003319.4) | Missense Mutation (SNP) | VAF 84/477 reads (18%) | PolyPhen benign (0.018); called by muse, mutect2, varscan2
- USP26 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 69/432 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WAPL | c.3400C>T p.Q1134* | Nonsense Mutation (SNP) | VAF 40/307 reads (13%) | called by muse, mutect2, varscan2
- ZFHX4 | c.9914A>C p.Q3305P | Missense Mutation (SNP) | VAF 307/688 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF229 | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 101/455 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF284 | c.1657T>A p.C553S | Missense Mutation (SNP) | VAF 76/402 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF385B | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 87/449 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF503 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 142/613 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- ZNF556 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 124/570 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF729 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF738 | c.408A>T p.E136D | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.022); called by mutect2, varscan2
- ZNF804B | c.1907del p.K636Sfs*4 | Frame Shift Del (DEL) | VAF 50/474 reads (11%) | called by mutect2, pindel, varscan2
- ZSWIM2 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ABCA2 | c.4371C>T p.S1457= (on ENST00000614293; = p.S1427= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 123/587 reads (21%) | called by muse, mutect2, varscan2
- AC099489.1 | c.8322G>A p.L2774= | Silent (SNP) | VAF 89/421 reads (21%) | catalogued as rs1460760434; called by muse, mutect2, varscan2
- ACE | c.2334G>A p.R778= | Silent (SNP) | VAF 63/367 reads (17%) | called by muse, mutect2, varscan2
- ADCY8 | c.2550C>T p.F850= | Silent (SNP) | VAF 87/603 reads (14%) | catalogued as COSV53923505; called by muse, mutect2, varscan2
- ADCY8 | c.1945C>T p.L649= | Silent (SNP) | VAF 233/557 reads (42%) | catalogued as rs867990325, COSV53917837; called by muse, mutect2, varscan2
- ADD2 | c.411C>T p.I137= | Silent (SNP) | VAF 97/403 reads (24%) | catalogued as rs781971404; called by muse, mutect2, varscan2
- ADGRV1 | c.10296C>T p.S3432= | Silent (SNP) | VAF 92/439 reads (21%) | called by muse, mutect2, varscan2
- ALDH18A1 | c.177G>A p.K59= | Silent (SNP) | VAF 87/404 reads (22%) | called by muse, mutect2, varscan2
- ALDH1B1 | c.978C>T p.F326= | Silent (SNP) | VAF 99/506 reads (20%) | catalogued as rs746866232, COSV100890891; called by muse, mutect2, varscan2
- AMOTL1 | c.1716G>A p.E572= | Silent (SNP) | VAF 99/512 reads (19%) | called by muse, mutect2, varscan2
- ANKRD34C | c.723G>A p.R241= | Silent (SNP) | VAF 410/924 reads (44%) | catalogued as rs776080071; called by muse, mutect2, varscan2
- APOA2 | c.270C>T p.F90= | Silent (SNP) | VAF 168/418 reads (40%) | catalogued as rs752976925, COSV57153940; called by muse, mutect2, varscan2
- APOB | c.3579C>T p.F1193= | Silent (SNP) | VAF 70/337 reads (21%) | catalogued as rs267599187, COSV51922866; called by muse, mutect2, varscan2
- ARHGAP17 | c.987G>A p.R329= | Silent (SNP) | VAF 41/246 reads (17%) | catalogued as COSV51511042; called by muse, mutect2, varscan2
- ARHGEF11 | c.3756C>T p.S1252= | Silent (SNP) | VAF 337/754 reads (45%) | catalogued as COSV59354708; called by muse, mutect2, varscan2
- ARL16 | c.72A>G p.G24= | Silent (SNP) | VAF 102/502 reads (20%) | called by muse, mutect2, varscan2
- ARMC4 | c.2304G>A p.Q768= | Silent (SNP) | VAF 92/373 reads (25%) | catalogued as COSV59466686; called by muse, mutect2, varscan2
- ASCC3 | c.3999A>G p.Q1333= | Silent (SNP) | VAF 160/403 reads (40%) | called by muse, mutect2, varscan2
- ASTN1 | c.1668A>G p.E556= | Silent (SNP) | VAF 88/637 reads (14%) | called by muse, mutect2, varscan2
- ASXL3 | c.4539C>T p.P1513= | Silent (SNP) | VAF 92/442 reads (21%) | catalogued as rs775636026; called by muse, mutect2, varscan2
- ATP1A1 | c.921C>T p.F307= | Silent (SNP) | VAF 95/506 reads (19%) | called by muse, mutect2, varscan2
- ATP7B | c.2319C>T p.F773= | Silent (SNP) | VAF 69/385 reads (18%) | called by muse, mutect2, varscan2
- ATXN1 | c.174G>A p.G58= | Silent (SNP) | VAF 294/817 reads (36%) | catalogued as rs201396331; called by muse, mutect2, varscan2
- BMP7 | c.828C>T p.F276= | Silent (SNP) | VAF 292/759 reads (38%) | catalogued as rs201174398, COSV67780230; called by muse, mutect2, varscan2
- BRINP2 | c.183C>T p.D61= | Silent (SNP) | VAF 132/751 reads (18%) | catalogued as rs962477177; called by muse, mutect2, varscan2
- BRWD3 | c.4426T>C p.L1476= | Silent (SNP) | VAF 39/268 reads (15%) | catalogued as rs766293361; called by muse, mutect2, varscan2
- BTNL9 | c.171C>T p.F57= | Silent (SNP) | VAF 78/365 reads (21%) | catalogued as COSV59798949; called by muse, mutect2, varscan2
- C2orf73 | c.483G>A p.P161= | Silent (SNP) | VAF 43/243 reads (18%) | catalogued as rs759075981; called by muse, mutect2, varscan2
- CATSPERD | c.1908G>A p.K636= | Silent (SNP) | VAF 74/337 reads (22%) | called by muse, mutect2, varscan2
- CATSPERG | c.918C>T p.T306= | Silent (SNP) | VAF 75/433 reads (17%) | called by muse, mutect2, varscan2
- CBLC | c.474C>T p.T158= | Silent (SNP) | VAF 79/425 reads (19%) | called by muse, mutect2, varscan2
- CBY2 | c.582G>A p.K194= | Silent (SNP) | VAF 120/639 reads (19%) | called by muse, mutect2, varscan2
- CCDC102A | c.1362G>A p.K454= | Silent (SNP) | VAF 116/572 reads (20%) | called by muse, mutect2, varscan2
- CD244 | c.765G>A p.R255= (on ENST00000368033 / NM_001166663.2; = p.R250= on NM_016382.4) | Silent (SNP) | VAF 185/429 reads (43%) | catalogued as rs368410544; called by muse, mutect2, varscan2
- CENPJ | c.849C>T p.N283= | Silent (SNP) | VAF 44/232 reads (19%) | catalogued as rs773443821; called by muse, mutect2, varscan2
- CFAP61 | c.3408C>T p.I1136= | Silent (SNP) | VAF 64/288 reads (22%) | called by muse, mutect2, varscan2
- CFAP92 | c.2646G>A p.R882= | Silent (SNP) | VAF 67/331 reads (20%) | called by muse, mutect2, varscan2
- CHD6 | c.2094C>T p.I698= | Silent (SNP) | VAF 94/448 reads (21%) | called by muse, mutect2, varscan2
- CNGA3 | c.1492C>T p.L498= | Silent (SNP) | VAF 118/497 reads (24%) | catalogued as rs952757586; called by muse, mutect2, varscan2
- CNTN4 | c.2599T>C p.L867= | Silent (SNP) | VAF 78/471 reads (17%) | called by muse, mutect2, varscan2
- CRLF1 | c.942C>T p.N314= | Silent (SNP) | VAF 100/448 reads (22%) | called by muse, mutect2, varscan2
- CSF2RB | c.2523C>T p.S841= | Silent (SNP) | VAF 125/654 reads (19%) | catalogued as COSV53258866; called by muse, mutect2, varscan2
- CSNKA2IP | c.468A>G p.K156= | Silent (SNP) | VAF 70/321 reads (22%) | called by muse, mutect2, varscan2
- DNAH5 | c.13134G>A p.E4378= | Silent (SNP) | VAF 52/238 reads (22%) | called by muse, mutect2, varscan2
- DRGX | c.726C>T p.P242= | Silent (SNP) | VAF 107/561 reads (19%) | called by muse, mutect2, varscan2
- DUSP16 | c.123C>T p.H41= | Silent (SNP) | VAF 54/394 reads (14%) | catalogued as rs151208994; called by muse, mutect2, varscan2
- DUSP26 | c.156C>T p.L52= | Silent (SNP) | VAF 74/355 reads (21%) | called by muse, mutect2, varscan2
- EFCC1 | c.60C>T p.Y20= | Silent (SNP) | VAF 100/554 reads (18%) | called by muse, mutect2, varscan2
- ELOA2 | c.1494G>A p.R498= | Silent (SNP) | VAF 116/567 reads (20%) | catalogued as rs374902915; called by muse, mutect2, varscan2
- FAM83H | c.2814C>T p.T938= | Silent (SNP) | VAF 461/891 reads (52%) | called by muse, mutect2, varscan2
- FMO3 | c.948G>A p.G316= | Silent (SNP) | VAF 102/712 reads (14%) | catalogued as COSV63006739; called by muse, mutect2
- GAB1 | c.1326A>G p.E442= | Silent (SNP) | VAF 73/346 reads (21%) | called by muse, mutect2, varscan2
- GABRA6 | c.1119G>A p.R373= | Silent (SNP) | VAF 70/427 reads (16%) | catalogued as COSV99194297, COSV99194594; called by muse, mutect2
- GANAB | c.2364C>T p.P788= | Silent (SNP) | VAF 84/389 reads (22%) | called by muse, mutect2, varscan2
- GFRA1 | c.1320A>G p.P440= | Silent (SNP) | VAF 90/451 reads (20%) | called by muse, mutect2, varscan2
- GKN3P | c.39C>T p.F13= | Silent (SNP) | VAF 70/428 reads (16%) | catalogued as rs986816203; called by muse, mutect2, varscan2
- GMIP | c.444G>T p.L148= | Silent (SNP) | VAF 68/397 reads (17%) | called by muse, mutect2, varscan2
- GMPPA | c.204C>T p.F68= | Silent (SNP) | VAF 91/418 reads (22%) | catalogued as COSV100354806; called by muse, mutect2, varscan2
- GMPPA | c.405C>T p.H135= | Silent (SNP) | VAF 69/353 reads (20%) | called by muse, mutect2, varscan2
- GRIN2D | c.558C>T p.S186= | Silent (SNP) | VAF 102/474 reads (22%) | called by muse, mutect2, varscan2
- H1-4 | c.390G>A p.K130= | Silent (SNP) | VAF 110/674 reads (16%) | catalogued as rs760642724; called by muse, mutect2, varscan2
- HCRTR2 | c.174C>T p.I58= | Silent (SNP) | VAF 77/509 reads (15%) | catalogued as COSV63800178; called by muse, mutect2, varscan2
- HHIPL1 | c.759C>T p.G253= | Silent (SNP) | VAF 114/522 reads (22%) | called by muse, mutect2, varscan2
- HIVEP1 | c.4554C>T p.I1518= | Silent (SNP) | VAF 185/541 reads (34%) | catalogued as rs569541352; called by muse, mutect2, varscan2
- HK3 | c.1614C>T p.F538= | Silent (SNP) | VAF 64/326 reads (20%) | called by muse, mutect2, varscan2
- HS3ST2 | c.1092C>T p.F364= | Silent (SNP) | VAF 39/237 reads (16%) | called by muse, mutect2, varscan2
- HYDIN | c.10392C>T p.L3464= | Silent (SNP) | VAF 79/366 reads (22%) | catalogued as rs546026088, COSV66876767; called by muse, mutect2, varscan2
- IFNA17 | c.192G>A p.E64= | Silent (SNP) | VAF 93/364 reads (26%) | called by muse, mutect2, varscan2
- ITPR1 | c.4362C>T p.F1454= (on ENST00000354582; = p.F1439= on NM_002222.7) | Silent (SNP) | VAF 53/249 reads (21%) | called by muse, mutect2, varscan2
- KCTD8 | c.1008G>A p.R336= | Silent (SNP) | VAF 59/282 reads (21%) | called by muse, mutect2, varscan2
- KDM6B | c.2710C>T p.L904= | Silent (SNP) | VAF 89/412 reads (22%) | called by muse, mutect2, varscan2
- KEL | c.1671C>T p.L557= | Silent (SNP) | VAF 100/686 reads (15%) | catalogued as rs1357811778, COSV100786919; called by muse, mutect2, varscan2
- LGR5 | c.879C>T p.I293= | Silent (SNP) | VAF 24/195 reads (12%) | called by muse, mutect2, varscan2
- MAGI1 | c.2526C>T p.I842= (on ENST00000402939 / NM_001033057.2; = p.I870= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/278 reads (21%) | catalogued as rs1348098781, COSV58340296, COSV58344143; called by muse, mutect2, varscan2
- MAP1A | c.2794T>C p.L932= | Silent (SNP) | VAF 187/478 reads (39%) | catalogued as COSV55808418; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2529G>T p.L843= | Silent (SNP) | VAF 130/639 reads (20%) | called by muse, mutect2, varscan2
- MCM3 | c.30C>T p.L10= | Silent (SNP) | VAF 57/370 reads (15%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.693C>T p.P231= | Silent (SNP) | VAF 116/820 reads (14%) | catalogued as rs1266910036; called by muse, mutect2, varscan2
- MTCH1 | c.417C>T p.I139= | Silent (SNP) | VAF 82/408 reads (20%) | catalogued as rs755385100, COSV65320924; called by muse, mutect2, varscan2
- MUC16 | c.8229G>A p.S2743= | Silent (SNP) | VAF 91/380 reads (24%) | catalogued as COSV101198441, COSV67443037; called by muse, mutect2, varscan2
- MUC6 | c.7029C>T p.P2343= | Silent (SNP) | VAF 93/481 reads (19%) | called by muse, mutect2, varscan2
- MYH8 | c.4737C>T p.I1579= | Silent (SNP) | VAF 79/375 reads (21%) | catalogued as rs368912522; called by muse, mutect2, varscan2
- MYO18B | c.7323C>T p.F2441= | Silent (SNP) | VAF 97/553 reads (18%) | catalogued as rs762049627, COSV59130595; called by muse, mutect2, varscan2
- MYO1F | c.3270C>T p.F1090= | Silent (SNP) | VAF 83/408 reads (20%) | catalogued as COSV57793512; called by muse, mutect2, varscan2
- NELL2 | c.81C>T p.S27= | Silent (SNP) | VAF 95/352 reads (27%) | called by muse, mutect2, varscan2
- NKD1 | c.1050G>A p.K350= | Silent (SNP) | VAF 126/616 reads (20%) | called by muse, mutect2, varscan2
- NLRP12 | c.1191C>T p.L397= | Silent (SNP) | VAF 102/505 reads (20%) | catalogued as COSV60751270; called by muse, mutect2, varscan2
- NSUN5 | c.1065C>G p.V355= | Silent (SNP) | VAF 119/787 reads (15%) | called by muse, mutect2, varscan2
- OPN4 | c.1416C>A p.P472= | Silent (SNP) | VAF 79/426 reads (19%) | called by muse, mutect2, varscan2
- OR10R2 | c.141C>T p.L47= | Silent (SNP) | VAF 68/630 reads (11%) | catalogued as COSV63768552; called by muse, mutect2, varscan2
- OR13C9 | c.114C>T p.I38= | Silent (SNP) | VAF 59/421 reads (14%) | catalogued as COSV52243183; called by muse, mutect2, varscan2
- OR14A16 | c.132C>T p.I44= | Silent (SNP) | VAF 206/492 reads (42%) | catalogued as COSV62927464; called by muse, mutect2, varscan2
- OR2T8 | c.78C>T p.F26= | Silent (SNP) | VAF 60/577 reads (10%) | catalogued as COSV60661743; called by muse, mutect2, varscan2
- OR2Z1 | c.618C>T p.I206= | Silent (SNP) | VAF 71/397 reads (18%) | catalogued as COSV60692728; called by muse, mutect2, varscan2
- OR5L2 | c.675C>T p.I225= | Silent (SNP) | VAF 84/404 reads (21%) | catalogued as COSV101004267, COSV65723787, COSV65725524; called by muse, mutect2, varscan2
- OR6P1 | c.939G>A p.R313= | Silent (SNP) | VAF 163/421 reads (39%) | called by muse, mutect2, varscan2
- OR8H2 | c.600C>T p.F200= | Silent (SNP) | VAF 51/309 reads (17%) | catalogued as COSV57947606; called by muse, mutect2, varscan2
- PADI1 | c.1143C>T p.F381= | Silent (SNP) | VAF 63/326 reads (19%) | catalogued as rs770038921, COSV64937691; called by muse, mutect2
- PADI3 | c.1005C>T p.T335= | Silent (SNP) | VAF 79/373 reads (21%) | called by muse, mutect2, varscan2
- PCDHA12 | c.318G>A p.L106= | Silent (SNP) | VAF 117/651 reads (18%) | catalogued as rs376091049; called by muse, mutect2, varscan2
- PCDHAC1 | c.2106C>T p.F702= | Silent (SNP) | VAF 85/421 reads (20%) | catalogued as rs1448389331, COSV53855580; called by muse, mutect2, varscan2
- PCDHGA5 | c.2247C>T p.F749= | Silent (SNP) | VAF 104/644 reads (16%) | catalogued as COSV53909247; called by muse, mutect2, varscan2
- PHLDA1 | c.423G>A p.R141= | Silent (SNP) | VAF 85/479 reads (18%) | called by muse, mutect2, varscan2
- PKDREJ | c.1006C>T p.L336= | Silent (SNP) | VAF 93/545 reads (17%) | called by muse, mutect2, varscan2
- PLEKHG4 | c.1672C>T p.L558= | Silent (SNP) | VAF 58/286 reads (20%) | called by muse, mutect2, varscan2
- POF1B | c.1185T>C p.S395= | Silent (SNP) | VAF 63/311 reads (20%) | called by muse, mutect2, varscan2
- POU4F2 | c.321G>C p.L107= | Silent (SNP) | VAF 91/415 reads (22%) | called by muse, mutect2, varscan2
- PPP1R3A | c.130C>A p.R44= | Silent (SNP) | VAF 60/466 reads (13%) | catalogued as COSV52878806; called by muse, mutect2, varscan2
- PRMT3 | c.1326C>T p.I442= | Silent (SNP) | VAF 30/205 reads (15%) | catalogued as COSV58181488; called by muse, mutect2, varscan2
- RBM10 | c.2787C>T p.A929= | Silent (SNP) | VAF 68/323 reads (21%) | called by muse, mutect2, varscan2
- ROS1 | c.3024G>A p.L1008= | Silent (SNP) | VAF 113/303 reads (37%) | called by muse, mutect2, varscan2
- RTL1 | c.2988G>A p.V996= | Silent (SNP) | VAF 136/542 reads (25%) | called by muse, mutect2, varscan2
- SCML2 | c.912C>T p.I304= | Silent (SNP) | VAF 47/286 reads (16%) | catalogued as COSV99318774; called by muse, mutect2, varscan2
- SCN11A | c.1020G>A p.T340= | Silent (SNP) | VAF 32/326 reads (10%) | catalogued as rs267599814, COSV56565234; called by muse, mutect2, varscan2
- SCN4A | c.3762G>A p.V1254= | Silent (SNP) | VAF 111/464 reads (24%) | called by muse, mutect2, varscan2
- SF3B1 | c.2163C>T p.I721= | Silent (SNP) | VAF 79/397 reads (20%) | catalogued as rs1356379586; called by muse, mutect2, varscan2
- SHISA6 | c.1335C>T p.H445= (on ENST00000409168 / NM_001173461.1; = p.H496= on NM_207386.4) | Silent (SNP) | VAF 94/531 reads (18%) | catalogued as rs1327422586; called by muse, mutect2, varscan2
- SHROOM1 | c.2070G>A p.V690= | Silent (SNP) | VAF 138/565 reads (24%) | called by muse, mutect2, varscan2
- SHROOM3 | c.5649C>T p.I1883= | Silent (SNP) | VAF 49/260 reads (19%) | catalogued as rs1352159634, COSV56025125; called by muse, mutect2, varscan2
- SLC8A3 | c.1254G>A p.V418= | Silent (SNP) | VAF 75/435 reads (17%) | called by muse, mutect2, varscan2
- SMYD5 | c.129G>A p.R43= | Silent (SNP) | VAF 95/412 reads (23%) | catalogued as COSV50264814; called by muse, mutect2, varscan2
- SP140 | c.216C>T p.F72= | Silent (SNP) | VAF 54/265 reads (20%) | called by muse, mutect2, varscan2
- ST14 | c.189C>T p.I63= | Silent (SNP) | VAF 99/420 reads (24%) | catalogued as rs768216252; called by muse, mutect2, varscan2
- STAB2 | c.4545C>T p.N1515= | Silent (SNP) | VAF 84/304 reads (28%) | called by muse, mutect2, varscan2
- TAS2R39 | c.222G>A p.R74= | Silent (SNP) | VAF 71/613 reads (12%) | catalogued as COSV101489413; called by muse, mutect2, varscan2
- TBC1D9 | c.3288C>T p.F1096= | Silent (SNP) | VAF 123/532 reads (23%) | catalogued as rs1346145635; called by muse, mutect2, varscan2
- TBX19 | c.420C>T p.I140= | Silent (SNP) | VAF 77/567 reads (14%) | called by muse, mutect2, varscan2
- TECTA | c.2220G>T p.L740= | Silent (SNP) | VAF 123/423 reads (29%) | called by muse, mutect2, varscan2
- TFF1 | c.195C>T p.V65= | Silent (SNP) | VAF 70/403 reads (17%) | catalogued as COSV52299198; called by muse, mutect2, varscan2
- TMEFF2 | c.966C>T p.I322= | Silent (SNP) | VAF 63/415 reads (15%) | catalogued as rs147945335; called by muse, mutect2, varscan2
- TMEM178B | c.270C>T p.A90= | Silent (SNP) | VAF 379/918 reads (41%) | called by muse, mutect2, varscan2
- TMEM38B | c.477G>A p.T159= | Silent (SNP) | VAF 43/241 reads (18%) | catalogued as rs750450882, COSV65949732; called by muse, mutect2, varscan2
- TMEM62 | c.1539C>T p.S513= | Silent (SNP) | VAF 102/281 reads (36%) | called by muse, mutect2, varscan2
- TRBC2 | c.63C>A p.I21= | Silent (SNP) | VAF 64/351 reads (18%) | called by muse, mutect2, varscan2
- TRIM71 | c.942C>T p.L314= | Silent (SNP) | VAF 118/483 reads (24%) | called by muse, mutect2, varscan2
- TRPC5 | c.585C>T p.S195= | Silent (SNP) | VAF 126/609 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.66957C>T p.I22319= (on ENST00000591111; = p.I14895= on NM_003319.4) | Silent (SNP) | VAF 116/442 reads (26%) | catalogued as COSV100599747, COSV59958093; called by muse, mutect2, varscan2
- TTN | c.59991C>T p.N19997= (on ENST00000591111; = p.N12573= on NM_003319.4) | Silent (SNP) | VAF 86/463 reads (19%) | called by muse, mutect2, varscan2
- TUBGCP2 | c.916C>T p.L306= | Silent (SNP) | VAF 109/522 reads (21%) | catalogued as rs764408048; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2169C>T p.P723= | Silent (SNP) | VAF 98/571 reads (17%) | catalogued as rs1561815988; called by muse, mutect2, varscan2
- UNC5A | c.2346G>A p.Q782= | Silent (SNP) | VAF 51/223 reads (23%) | called by muse, mutect2, varscan2
- USH1G | c.834G>A p.S278= | Silent (SNP) | VAF 119/520 reads (23%) | called by muse, mutect2, varscan2
- VARS1 | c.1122C>T p.T374= | Silent (SNP) | VAF 230/727 reads (32%) | called by muse, mutect2, varscan2
- WAPL | c.3399C>T p.C1133= | Silent (SNP) | VAF 40/306 reads (13%) | called by muse, mutect2, varscan2
- WDFY4 | c.447G>A p.G149= | Silent (SNP) | VAF 67/372 reads (18%) | called by muse, mutect2, varscan2
- XXYLT1 | c.981C>T p.H327= | Silent (SNP) | VAF 137/664 reads (21%) | called by muse, mutect2, varscan2
- ZAP70 | c.993C>T p.F331= | Silent (SNP) | VAF 108/477 reads (23%) | called by muse, mutect2, varscan2
- ZFHX4 | c.10605C>T p.A3535= | Silent (SNP) | VAF 99/565 reads (18%) | catalogued as rs754925632; called by muse, mutect2, varscan2
- ZNF175 | c.1788C>T p.F596= | Silent (SNP) | VAF 73/431 reads (17%) | called by muse, mutect2, varscan2
- ZNF284 | c.1656A>G p.S552= | Silent (SNP) | VAF 75/404 reads (19%) | called by muse, mutect2, varscan2
- ZNF385C | c.927G>A p.K309= | Silent (SNP) | VAF 79/424 reads (19%) | called by muse, mutect2, varscan2
- ZNF513 | c.661C>T p.L221= | Silent (SNP) | VAF 132/710 reads (19%) | catalogued as COSV99278001; called by muse, mutect2, varscan2
- ZNF679 | c.249A>T p.V83= | Silent (SNP) | VAF 127/319 reads (40%) | called by muse, mutect2, varscan2
- ZNF728 | c.726C>T p.I242= | Silent (SNP) | VAF 44/252 reads (17%) | catalogued as COSV74099709; called by muse, mutect2, varscan2
- ZNF74 | c.744C>T p.F248= | Silent (SNP) | VAF 287/814 reads (35%) | catalogued as rs763367647, COSV62623263; called by muse, mutect2, varscan2
- ZNF80 | c.459G>A p.V153= | Silent (SNP) | VAF 80/419 reads (19%) | called by muse, mutect2, varscan2
- ZNF804A | c.3174A>T p.P1058= | Silent (SNP) | VAF 83/431 reads (19%) | called by muse, mutect2, varscan2
- ZNF91 | c.1515T>C p.L505= | Silent (SNP) | VAF 32/208 reads (15%) | called by muse, varscan2
- AC136777.2 | chr8:261077 G>A | 5'Flank (SNP) | VAF 76/347 reads (22%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840370 C>A | 5'Flank (SNP) | VAF 132/721 reads (18%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825813 C>T | 5'Flank (SNP) | VAF 54/297 reads (18%) | catalogued as rs1441970992; called by muse, mutect2, varscan2
- ANKRD6 | c.792+116A>G | Intron (SNP) | VAF 132/302 reads (44%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.86-11C>T | Intron (SNP) | VAF 97/463 reads (21%) | called by muse, mutect2, varscan2
- COBL | c.1096+11800C>T | Intron (SNP) | VAF 254/600 reads (42%) | called by muse, mutect2, varscan2
- CTCFL | c.1674+837A>G | Intron (SNP) | VAF 263/672 reads (39%) | called by muse, mutect2, varscan2
- DEFB119 | c.61+1324G>A | Intron (SNP) | VAF 93/408 reads (23%) | catalogued as COSV59266812; called by muse, mutect2, varscan2
- DST | c.4296+4686C>T | Intron (SNP) | VAF 164/525 reads (31%) | catalogued as rs760447065; called by muse, mutect2, varscan2
- FLYWCH2 | c.322+109C>T | Intron (SNP) | VAF 89/383 reads (23%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+1926A>T | Intron (SNP) | VAF 143/725 reads (20%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+14068T>G | Intron (SNP) | VAF 44/264 reads (17%) | called by muse, mutect2, varscan2
- MUCL3 | c.946+1292G>A | Intron (SNP) | VAF 174/984 reads (18%) | called by muse, mutect2, varscan2
- PIGN | c.2672+2219A>C | Intron (SNP) | VAF 73/389 reads (19%) | called by muse, mutect2, varscan2
- RREB1 | c.3809-5887C>T | Intron (SNP) | VAF 204/588 reads (35%) | called by muse, mutect2, varscan2
- RXFP1 | c.465-891G>A | Intron (SNP) | VAF 65/335 reads (19%) | called by muse, mutect2, varscan2
- SLC22A5 | c.394-160C>T | Intron (SNP) | VAF 64/348 reads (18%) | called by muse, mutect2, varscan2
- SPATA8 | n.273G>A | RNA (SNP) | VAF 347/762 reads (46%) | catalogued as rs267604397, COSV60703913; called by muse, mutect2, varscan2
- ST3GAL3 | c.1083+702C>T | Intron (SNP) | VAF 77/360 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.34265-2976C>A | Intron (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- UMODL1 | c.1899+189G>A | Intron (SNP) | VAF 160/825 reads (19%) | catalogued as rs542395191; called by muse, mutect2, varscan2
- URM1 | c.237+25C>T | Intron (SNP) | VAF 126/547 reads (23%) | catalogued as COSV65717182; called by muse, mutect2, varscan2
- ZDBF2 | c.61-5171G>A | Intron (SNP) | VAF 51/292 reads (17%) | called by muse, mutect2, varscan2
